Gene-level copy-number profile of tumor specimen TCGA-L5-A8NQ-01A from TCGA case TCGA-L5-A8NQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 71.9 years (26,250 days).
Specimen TCGA-L5-A8NQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.55a537eb-b053-4436-b92b-ae36229c0c31.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A8NQ-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6e108603-62dd-4b9d-9a8f-e0ecc93ccb66

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 32,202; copy number 2: 17,867; copy number 3: 8,984; copy number 4: 545; copy number 5: 19; copy number 6: 22; copy number 9: 83; copy number 17: 59; copy number 23: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A8NQ-01A-11D-A36I-01): tumor purity 0.19, ploidy 2.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:135,882,780–135,888,133, 1 gene (within-gene range 0–2): AL360178.2.
- chr10:34,663,859–34,676,041, 2 genes: RPL37P18, RPS12P16.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 9,748 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,030,284–119,818,485, 363 genes, copy number 3 (broad region; genes not listed).
- chr3:188,153,284–188,890,671, 1 gene, copy number 3 (within-gene range 2–3): LPP.
- chr3:188,562,238–198,222,513, 219 genes, copy number 3 (broad region; genes not listed).
- chr5:28,213,359–45,895,970, 283 genes, copy number 3 (broad region; genes not listed).
- chr6:167,607–74,004,812, 1,667 genes, copy number 3 (broad region; genes not listed).
- chr6:122,443,351–126,203,817, 35 genes, copy number 4 (within-gene range 2–4): SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2, AL512283.1, AL512283.3, RN7SL564P, FABP7, SMPDL3A, ATP5MGP2, AL591428.1, CLVS2, TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1, RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11.
- chr8:127,289,817–145,066,685, 338 genes, copy number 3 (broad region; genes not listed).
- chr10:52,389,112–53,766,614, 11 genes, copy number 3: RPL31P44, THAP12P3, LNCAROD, MBL2, Y_RNA, AC073174.1, LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1.
- chr10:117,425,194–130,962,668, 207 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr10:131,095,218–131,095,777, 1 gene, copy number 3: TCERG1L-AS1.
- chr11:67,119,263–71,997,597, 178 genes, copy number 9–23 (within-gene range 1–23) (broad region; genes not listed).
- chr12:66,767–33,576,200, 837 genes, copy number 3–5 (broad region; genes not listed).
- chr14:18,333,726–33,804,176, 581 genes, copy number 3 (broad region; genes not listed).
- chr14:35,897,936–36,068,261, 1 gene, copy number 4 (within-gene range 1–4): AL133304.3.
- chr14:36,054,197–106,875,071, 1,649 genes, copy number 3–4 (broad region; genes not listed).
- chr15:19,878,555–34,969,742, 523 genes, copy number 3–6 (within-gene range 1–6) (broad region; genes not listed).
- chr15:89,830,599–101,933,350, 292 genes, copy number 3 (broad region; genes not listed).
- chr16:46,469,341–90,222,851, 1,141 genes, copy number 3 (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 3 (broad region; genes not listed).
- chr20:4,475,638–12,381,255, 124 genes, copy number 3 (broad region; genes not listed).
- chr20:26,167,817–64,313,132, 921 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 29,781. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
